Gene-level copy-number profile of tumor specimen TCGA-95-7944-01A from TCGA case TCGA-95-7944, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 71.2 years (26,003 days).
Specimen TCGA-95-7944-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.31992e33-6cdf-4166-a411-d7e14d9a27af.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-95-7944-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 845 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/8924ab61-9db2-4418-9b1f-1d5f5e47effb

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 103; copy number 1: 23,687; copy number 2: 33,152; copy number 3: 2,409; copy number 4: 152; copy number 6: 210; copy number 7: 65.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-95-7944-01A-11D-2183-01): tumor purity 0.41, ploidy 1.64, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 95 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:21,962,819–22,530,378, 95 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 275 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:97,998,325–100,568,220, 107 genes, copy number 6 (broad region; genes not listed).
- chr7:117,604,791–117,874,139, 2 genes, copy number 6 (within-gene range 1–6): AC000061.1, CTTNBP2.
- chr7:128,297,685–134,998,153, 161 genes, copy number 6–7 (broad region; genes not listed).
- chr7:136,685,559–137,182,107, 5 genes, copy number 7 (within-gene range 4–7): AC009264.1, PSMC1P3, CHRM2, MIR490, KRT8P51.

Autosomal genes at a single copy (total copy number 1): 21,308. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
